Somatic mutation profile of tumor specimen ALCH-B0EO-TTP1-A (aliquot ALCH-B0EO-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0EO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.7 years (25,096 days).
Specimen ALCH-B0EO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1464eac-897b-4615-aaec-c6f5c1cc3aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EO-NB1-A (Blood Derived Normal), aliquot ALCH-B0EO-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb34009e-d1d1-4695-9727-6e85c59bae4b

The open-access MAF lists 329 somatic variants for this specimen: 215 protein-altering or splice-affecting, 66 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 66, Intron 27, Nonsense Mutation 16, 3'UTR 6, RNA 6, Splice Site 4, 5'UTR 4, 3'Flank 3, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 129/412 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSL3 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 32/191 reads (17%) | catalogued as rs1411651413; called by muse, mutect2, varscan2
- ADGRE2 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs139418141; called by muse, mutect2, varscan2
- AKAP12 | c.1864C>A p.R622S | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53583621; called by muse, mutect2
- ALMS1 | c.9781+1G>T p.X3261_splice | Splice Site (SNP) | VAF 49/352 reads (14%) | catalogued as COSV52522446; called by muse, mutect2, varscan2
- ARFGEF2 | c.3496A>T p.M1166L | Missense Mutation (SNP) | VAF 66/589 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV64213986; called by muse, mutect2, varscan2
- ARHGAP5 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61535731; called by muse, mutect2, varscan2
- BRCA2 | c.2245A>G p.S749G | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs80358495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSND | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 21/558 reads (4%) | catalogued as COSV64871204; called by muse, mutect2
- C2CD4C | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs930570992, COSV59967713; called by muse, mutect2, varscan2
- C2orf16 | c.5711C>T p.S1904F | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.217); catalogued as rs746206732; called by muse, mutect2
- C5orf34 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs941153905; called by muse, mutect2
- COL5A3 | c.5082T>A p.D1694E | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1230861738; called by muse, mutect2, varscan2
- CPAMD8 | c.4780G>A p.D1594N (on ENST00000651564; = p.D1547N on NM_015692.5) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs372159148; called by muse, mutect2, varscan2
- CPXCR1 | c.153G>T p.R51S | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV52162795; called by muse, mutect2
- CRB2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs536555517; called by muse, mutect2, varscan2
- DLEC1 | c.3991G>C p.E1331Q | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV57302071; called by muse, mutect2
- DSCAM | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs770132126, COSV68020895; called by muse, varscan2
- DUSP6 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1380980909; called by muse, mutect2
- ERO1B | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV59241813; called by muse, varscan2
- EVC | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 38/634 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs1395596111, COSV53829401, COSV53831513; called by muse, mutect2
- FAP | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV51862146; called by muse, mutect2, varscan2
- FBXO2 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs371498795; called by muse, mutect2, varscan2
- GMFG | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs370207146; called by muse, mutect2, varscan2
- GMIP | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1349137652, COSV52558699; called by muse, mutect2, varscan2
- HNRNPH2 | c.1188G>C p.M396I | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs147663358; called by muse, mutect2
- INPP5B | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); catalogued as rs747840541; called by mutect2, varscan2
- IQCB1 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV100182127, COSV60435964; called by muse, mutect2
- JMJD1C | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV101232474; called by muse, mutect2
- LAMA5 | c.6928G>A p.E2310K | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV53363270; called by muse, mutect2
- LIG3 | c.1022T>C p.M341T | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761204337; called by muse, mutect2, varscan2
- LIPE | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 25/381 reads (7%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.007); catalogued as rs1401918188; called by muse, mutect2
- LMTK2 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99033181; called by muse, mutect2, varscan2
- LRPPRC | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs1418745026; called by muse, mutect2
- MFAP3L | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1055702833; called by muse, mutect2
- MUC16 | c.1793C>G p.P598R | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as COSV101200082; called by muse, mutect2
- MYL12B | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV52898107; called by muse, mutect2
- NEURL3 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461594901; called by muse, mutect2
- NT5C1B | c.1421C>T p.S474F (on ENST00000359846 / NM_001199086.2; = p.S414F on NM_033253.4) | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1432252729; called by muse, mutect2
- NUCB1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 33/555 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs973071718; called by muse, mutect2
- OR14C36 | c.720C>G p.I240M | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs1278080793, COSV58602682; called by muse, mutect2
- PCDHA13 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 59/722 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV56524320; called by muse, mutect2
- PDZRN3 | c.1725C>A p.D575E | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs765452154, COSV55199524; called by muse, mutect2, varscan2
- PIEZO2 | c.4532T>A p.M1511K | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1322560539; called by muse, mutect2
- PLXNA2 | c.3304C>G p.L1102V | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.377); catalogued as rs1373220753; called by muse, mutect2
- PPARGC1A | c.475A>G p.N159D | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.551); catalogued as rs372840138; called by muse, mutect2
- PPFIA2 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | catalogued as rs867357851; called by muse, mutect2
- PROM1 | c.2395G>T p.G799* | Nonsense Mutation (SNP) | VAF 30/341 reads (9%) | catalogued as COSV71699473; called by muse, mutect2
- RLF | c.3152C>G p.S1051C | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV65651971; called by muse, mutect2
- SCARB1 | c.1383C>G p.I461M | Missense Mutation (SNP) | VAF 40/648 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs1322833796; called by muse, mutect2
- SETX | c.3466G>C p.E1156Q | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as CD068655; called by muse, mutect2
- SIGLEC8 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58472577; called by muse, mutect2, varscan2
- SLC44A5 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100901578, COSV63771932; called by muse, mutect2
- SLC7A14 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 70/538 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755029338, COSV51581859; called by muse, mutect2, varscan2
- SLC7A5 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as rs777363728; called by muse, mutect2
- SPATC1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554756008; called by muse, mutect2, varscan2
- SRRM2 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV57081727; called by muse, mutect2
- SYMPK | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99841684; called by muse, mutect2, varscan2
- SYNE4 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as rs1465902381; called by muse, mutect2
- TBX19 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs777264530; called by muse, mutect2, varscan2
- TCEAL6 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV101035940; called by muse, mutect2
- TDRD12 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.332); catalogued as rs1183926304, COSV70015365; called by muse, mutect2
- TECRL | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as rs1374891030, COSV101168610; called by muse, mutect2
- THSD4 | c.1737G>C p.E579D | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55964904; called by muse, mutect2
- TNN | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV53421489; called by muse, mutect2
- TP53BP1 | c.2600C>G p.S867* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV55511364; called by muse, mutect2, varscan2
- TRPC3 | c.739G>A p.E247K (on ENST00000379645 / NM_001366479.2; = p.E174K on NM_003305.2) | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868163943, COSV53377777; called by muse, mutect2
- UFL1 | c.797A>T p.Y266F | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV65149238; called by muse, mutect2, varscan2
- VWA5B1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.406); catalogued as rs1048425237, COSV57053319; called by muse, mutect2
- WDR13 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54331639; called by muse, mutect2
- ZNF223 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1250854378; called by muse, mutect2, varscan2
- ZNF319 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.878); catalogued as COSV99540142; called by muse, mutect2
- ZNF385B | c.117G>C p.L39F | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1301196403; called by muse, mutect2
- ZNF599 | c.1358G>A p.C453Y | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776112726; called by muse, mutect2, varscan2
- ZNF680 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV100549203; called by muse, mutect2, varscan2
- ZNF98 | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV63335686; called by muse, varscan2
- ABCB5 | c.3608C>A p.T1203K (on ENST00000404938 / NM_001163941.2; = p.T758K on NM_178559.6) | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADA2 | c.1153G>A p.G385R (on ENST00000262607; = p.G144R on NM_177405.3) | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADGB | c.3649G>T p.G1217C | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.174); called by muse, mutect2
- ADGRG1 | c.1948C>G p.Q650E | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- AIPL1 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMMECR1 | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- AMPD1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- ANK2 | c.2503G>A p.V835I | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- APC2 | c.1754T>A p.L585Q | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOB | c.3773T>A p.L1258Q | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2A1 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 92/505 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- BIRC6 | c.10766G>T p.S3589I | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BORA | c.1582G>C p.D528H (on ENST00000613797; = p.D453H on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2
- BRINP2 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- BRSK1 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 13/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1orf43 | c.628C>G p.Q210E (on ENST00000368521 / NM_001297718.2; = p.Q176E on NM_015449.4) | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf132 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- C6orf136 | c.640G>C p.E214Q (on ENST00000376473 / NM_001109938.3; = p.E80Q on NM_145029.4) | Missense Mutation (SNP) | VAF 44/793 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- C9 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 34/618 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); called by muse, mutect2
- CACNG2 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- CASP4 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC22 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- CCDC74B | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CDC45 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- CDHR2 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CNGA2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); called by muse, mutect2
- CNKSR2 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by mutect2, varscan2
- CNTNAP5 | c.81C>A p.N27K | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- COL4A6 | c.2017G>T p.G673* | Nonsense Mutation (SNP) | VAF 45/327 reads (14%) | called by muse, mutect2, varscan2
- COL9A1 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 58/756 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CREB3L2 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CSGALNACT1 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 28/473 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.088); called by muse, mutect2
- CSMD3 | c.5660G>A p.G1887E (on ENST00000297405 / NM_001363185.1; = p.G1783E on NM_052900.3) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- CTNNA2 | c.2201del p.P734Hfs*2 | Frame Shift Del (DEL) | VAF 28/211 reads (13%) | called by mutect2, pindel, varscan2
- DNMT1 | c.2402C>G p.T801R | Missense Mutation (SNP) | VAF 40/580 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.58); called by muse, mutect2
- DUOX1 | c.3995T>G p.L1332R | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELAVL4 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ENOX2 | c.1759G>T p.E587* (on ENST00000338144 / NM_001382520.1; = p.E558* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/298 reads (7%) | called by muse, mutect2
- EPN1 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ESF1 | c.1911G>C p.E637D | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- FAM135B | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBF1 | c.2635G>C p.E879Q (on ENST00000586717; = p.E893Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXL7 | c.759C>A p.C253* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | called by muse, varscan2
- FMNL3 | c.1463G>C p.R488T | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- GLG1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- GLIS2 | c.869A>G p.D290G | Missense Mutation (SNP) | VAF 56/816 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- GPATCH2L | c.1282A>G p.S428G | Missense Mutation (SNP) | VAF 24/477 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- GRM8 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HACE1 | c.2423G>C p.R808T | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2
- HAS3 | c.1118A>G p.H373R | Missense Mutation (SNP) | VAF 42/492 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HIVEP1 | c.4987G>T p.D1663Y | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- HJURP | c.354G>C p.E118D | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HROB | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 27/321 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2
- HS6ST2 | c.914A>C p.D305A | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HS6ST2 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- HUNK | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ICE2 | c.2752C>G p.H918D | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-16 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGLV2-33 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ITPR3 | c.3276C>G p.F1092L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); called by muse, mutect2
- KCNQ5 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 37/395 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCTD15 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- KDELR2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KLHL5 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LIN7B | c.275G>T p.R92M | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPAR1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.485); called by muse, varscan2
- MAP3K21 | c.2848C>G p.L950V | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAS1 | c.590T>A p.L197Q | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MAST4 | c.6358G>A p.E2120K (on ENST00000403625 / NM_001164664.2; = p.E1931K on NM_015183.3) | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MFSD6L | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.123); called by muse, mutect2
- MOV10L1 | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MUC12 | c.16300T>A p.W5434R (on ENST00000379442; = p.W5291R on NM_001164462.1) | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC16 | c.20093G>C p.R6698T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.9550C>A p.P3184T | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO15B | c.2905G>C p.E969Q | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.583); called by muse, mutect2
- NAV3 | c.4223C>G p.S1408C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR4A3 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- NT5C1B-RDH14 | c.1784+1G>A p.X595_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- NYX | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- OBI1 | c.1478G>C p.G493A | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2
- OMA1 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR1F1 | c.712T>A p.F238I | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- OR2J2 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- OR4K5 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR5D13 | c.422A>T p.K141M | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR5D18 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PARP6 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHA13 | c.2207A>C p.K736T | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); called by muse, mutect2
- PCDHB9 | c.1431C>G p.D477E | Missense Mutation (SNP) | VAF 61/917 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDE7B | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PELI1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- PIKFYVE | c.4528G>T p.D1510Y | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PKIG | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PLEKHA5 | c.1420A>T p.S474C | Missense Mutation (SNP) | VAF 130/591 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- POLR2A | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PRCP | c.365A>T p.H122L | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTGR2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- PTPRT | c.1865+2_1865+3del p.X622_splice | Splice Site (DEL) | VAF 21/151 reads (14%) | called by mutect2, pindel, varscan2
- RFX6 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- RNF169 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | called by muse, mutect2, varscan2
- RPS7 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 67/538 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- RTL4 | c.550T>A p.F184I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2
- RYR1 | c.10206C>G p.C3402W | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- RYR1 | c.12607del p.Q4203Sfs*7 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
- SCML1 | c.496C>T p.R166* (on ENST00000380041 / NM_001037540.3; = p.R139* on NM_006746.6) | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- SETD3 | c.1401G>T p.L467F | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMG1 | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- SNX15 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- SPAG5 | c.3040G>C p.E1014Q | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.603); called by muse, mutect2
- SPATA31E1 | c.2713G>C p.D905H | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SPATA31E1 | c.2975C>T p.S992L | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.205); called by muse, mutect2
- SPOPL | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- SSTR2 | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- STAT5A | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 30/492 reads (6%) | called by muse, mutect2
- SYT14 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 27/436 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.146); called by muse, mutect2
- TACSTD2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBC1D1 | c.3241G>C p.D1081H | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2
- TBC1D16 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TEX13C | c.2257C>A p.L753M | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.826); called by muse, mutect2
- THBD | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by mutect2, varscan2
- TLR7 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.348); called by muse, mutect2
- TMEM132B | c.1738T>C p.S580P | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- TMEM39B | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 25/387 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2
- TOMM40L | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TPCN2 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- TRPC4AP | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.112); called by muse, mutect2
- TTN | c.99242C>A p.T33081K (on ENST00000591111; = p.T25657K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/312 reads (11%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA3D | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VPS26A | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- VPS41 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- WDR7 | c.4460G>T p.R1487L | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- WDR97 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- ZBED1 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- ZNF107 | c.1123A>G p.K375E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ZNF219 | c.1630C>A p.H544N | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF251 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF572 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, varscan2
- ZNF804B | c.989A>T p.H330L | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- ZSCAN20 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2
- ABCA12 | c.3588G>T p.V1196= (on ENST00000272895 / NM_173076.3; = p.V878= on NM_015657.3) | Silent (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1047C>T p.H349= | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as rs368917702; called by muse, mutect2
- ANKRD46 | c.648G>A p.L216= | Silent (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- AP3D1 | c.1170C>T p.T390= | Silent (SNP) | VAF 24/480 reads (5%) | called by muse, mutect2
- ARHGEF11 | c.2646C>T p.L882= | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as COSV59354151; called by muse, mutect2
- ASB16 | c.351C>T p.I117= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as rs749205673; called by muse, mutect2
- CACNB2 | c.219G>T p.S73= (on ENST00000324631 / NM_201596.3; = p.S18= on NM_000724.4) | Silent (SNP) | VAF 36/457 reads (8%) | called by muse, mutect2
- CDH6 | c.408G>A p.G136= | Silent (SNP) | VAF 48/361 reads (13%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1032C>T p.G344= | Silent (SNP) | VAF 50/401 reads (12%) | catalogued as rs142122012, COSV62145397; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- DNMT3B | c.849C>T p.F283= | Silent (SNP) | VAF 36/480 reads (8%) | called by muse, mutect2
- EGR3 | c.345G>A p.P115= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as rs979115535; called by muse, mutect2, varscan2
- FAT3 | c.13623C>T p.L4541= | Silent (SNP) | VAF 51/331 reads (15%) | catalogued as rs758214772, COSV99969153; called by muse, mutect2, varscan2
- FNDC1 | c.5103C>T p.I1701= | Silent (SNP) | VAF 14/315 reads (4%) | catalogued as COSV51935720; called by muse, mutect2
- FOXA2 | c.1206C>G p.L402= (on ENST00000377115 / NM_153675.3; = p.L408= on NM_021784.5) | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as rs1448516922; called by muse, mutect2
- GCNT7 | c.792C>A p.P264= | Silent (SNP) | VAF 57/524 reads (11%) | called by muse, mutect2, varscan2
- GJA3 | c.426C>T p.A142= | Silent (SNP) | VAF 14/330 reads (4%) | called by muse, mutect2
- GOLGA6B | c.900A>T p.L300= | Silent (SNP) | VAF 26/281 reads (9%) | catalogued as rs1164397602; called by muse, mutect2, varscan2
- GP6 | c.930G>T p.P310= | Silent (SNP) | VAF 36/296 reads (12%) | catalogued as COSV59978261; called by muse, mutect2
- GRIP2 | c.1476G>T p.P492= (on ENST00000619221; = p.P395= on NM_001080423.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs769099965, COSV99817492; called by mutect2, varscan2
- HERC2 | c.6105C>T p.L2035= | Silent (SNP) | VAF 37/483 reads (8%) | called by muse, mutect2
- IGKV3D-7 | c.195G>T p.G65= | Silent (SNP) | VAF 38/507 reads (7%) | called by muse, varscan2
- KIF21B | c.2160C>T p.D720= | Silent (SNP) | VAF 60/770 reads (8%) | called by muse, mutect2
- KIF2B | c.1083G>T p.G361= | Silent (SNP) | VAF 38/316 reads (12%) | catalogued as COSV52129616; called by muse, mutect2, varscan2
- KLC4 | c.381G>A p.Q127= | Silent (SNP) | VAF 30/394 reads (8%) | catalogued as rs200464599; called by muse, mutect2
- LAMC3 | c.1953G>T p.L651= | Silent (SNP) | VAF 45/333 reads (14%) | called by muse, mutect2, varscan2
- LDHA | c.975G>A p.G325= | Silent (SNP) | VAF 22/255 reads (9%) | called by muse, mutect2
- LPA | c.4491T>C p.P1497= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- MAIP1 | c.492T>C p.F164= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2
- MAOA | c.27C>T p.I9= | Silent (SNP) | VAF 32/636 reads (5%) | called by muse, mutect2
- MMP2 | c.258A>T p.T86= | Silent (SNP) | VAF 56/600 reads (9%) | catalogued as COSV54604211; called by muse, mutect2
- MR1 | c.81G>C p.L27= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- MUC2 | c.3522T>C p.Y1174= | Silent (SNP) | VAF 54/389 reads (14%) | called by muse, mutect2, varscan2
- MYO15B | c.8007C>T p.L2669= | Silent (SNP) | VAF 12/213 reads (6%) | called by muse, mutect2
- NDUFS3 | c.564G>C p.L188= | Silent (SNP) | VAF 47/715 reads (7%) | catalogued as rs752782158; called by muse, mutect2
- NDUFS3 | c.705G>A p.L235= | Silent (SNP) | VAF 35/622 reads (6%) | catalogued as COSV55455564; called by muse, mutect2
- NLRP1 | c.1584T>G p.T528= | Silent (SNP) | VAF 34/284 reads (12%) | called by muse, mutect2, varscan2
- OPRK1 | c.1026G>T p.R342= | Silent (SNP) | VAF 13/373 reads (3%) | catalogued as COSV55569419; called by muse, mutect2
- OR11H4 | c.420G>A p.L140= | Silent (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- OR2L5 | c.204T>A p.I68= | Silent (SNP) | VAF 24/640 reads (4%) | called by muse, mutect2
- OR9A4 | c.756C>T p.Y252= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs782066072, COSV71884906, COSV71885528; called by muse, mutect2, varscan2
- PCDHB10 | c.363G>A p.L121= | Silent (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.1509C>A p.P503= | Silent (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2
- PRICKLE3 | c.711C>G p.V237= | Silent (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- PTH2R | c.164G>A p.*55= | Silent (SNP) | VAF 16/146 reads (11%) | called by muse, varscan2
- RELN | c.5934C>T p.I1978= | Silent (SNP) | VAF 37/362 reads (10%) | catalogued as rs141509094, COSV58994771; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.11886C>A p.S3962= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as COSV63691170; called by muse, mutect2, varscan2
- SALL1 | c.198T>C p.T66= | Silent (SNP) | VAF 80/591 reads (14%) | called by muse, mutect2, varscan2
- SALL3 | c.3693C>T p.S1231= | Silent (SNP) | VAF 27/245 reads (11%) | catalogued as rs774017269, COSV73305762; called by muse, mutect2, varscan2
- SLC10A1 | c.189C>T p.I63= | Silent (SNP) | VAF 27/460 reads (6%) | catalogued as rs201078426; ClinVar: uncertain significance; called by muse, mutect2
- SLC16A14 | c.1410T>C p.Y470= | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- SMG1 | c.1737C>G p.L579= | Silent (SNP) | VAF 74/623 reads (12%) | called by muse, mutect2, varscan2
- SPATA45 | c.132G>C p.L44= | Silent (SNP) | VAF 48/610 reads (8%) | catalogued as COSV60571542; called by muse, mutect2
- STK11IP | c.1704G>A p.E568= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- SVEP1 | c.7683C>T p.P2561= | Silent (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- TAS2R46 | c.810C>T p.S270= | Silent (SNP) | VAF 62/329 reads (19%) | called by muse, varscan2
- TBC1D31 | c.2904G>A p.A968= | Silent (SNP) | VAF 42/330 reads (13%) | catalogued as rs137957369; called by muse, mutect2, varscan2
- TBX10 | c.669C>A p.T223= | Silent (SNP) | VAF 50/434 reads (12%) | called by muse, mutect2, varscan2
- TCEAL6 | c.363C>A p.S121= | Silent (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- TFAP2B | c.720C>T p.L240= | Silent (SNP) | VAF 42/518 reads (8%) | called by muse, mutect2
- TMEM132C | c.747C>A p.G249= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- TRBV24-1 | c.303C>T p.I101= | Silent (SNP) | VAF 43/296 reads (15%) | catalogued as rs574268315; called by muse, mutect2, varscan2
- UBR4 | c.12822G>A p.R4274= | Silent (SNP) | VAF 32/432 reads (7%) | called by muse, mutect2
- USP4 | c.2565C>T p.V855= | Silent (SNP) | VAF 45/338 reads (13%) | called by muse, mutect2, varscan2
- WDR17 | c.2901T>C p.H967= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- ZAR1L | c.396C>A p.V132= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- ZNF469 | c.2382G>T p.A794= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- BCAP31 | c.*4C>T | 3'UTR (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99466058; called by muse, mutect2
- C10orf143 | c.69+2916G>T | Intron (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- C8B | c.*3G>A | 3'UTR (SNP) | VAF 24/455 reads (5%) | called by muse, mutect2
- CCDC138 | c.-28G>C | 5'UTR (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2, varscan2
- CD300LD | chr17:74592314 C>A | 5'Flank (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- CLRN1 | c.433+14T>A | Intron (SNP) | VAF 50/279 reads (18%) | called by muse, mutect2, varscan2
- COL6A1 | c.2251-34G>A | Intron (SNP) | VAF 52/347 reads (15%) | called by muse, mutect2, varscan2
- COX7B2 | c.-31G>T | 5'UTR (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- DENND10P1 | n.615G>T | RNA (SNP) | VAF 34/580 reads (6%) | catalogued as rs767330995; called by muse, mutect2
- FAM124A | c.101-6089G>T | Intron (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- FARP1 | c.*4910G>C | 3'UTR (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- GGTLC2 | chr22:22643885 A>G | 5'Flank (SNP) | VAF 43/723 reads (6%) | called by muse, mutect2
- IGFN1 | c.1241+1209A>T | Intron (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- IL10RA | c.67+173G>C | Intron (SNP) | VAF 44/868 reads (5%) | called by muse, mutect2
- INPP5B | c.772+96G>C | Intron (SNP) | VAF 25/427 reads (6%) | called by muse, mutect2
- IRAK1 | c.1303-51A>T | Intron (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- IRX6 | c.*39G>T | 3'UTR (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- ITIH5 | c.2032+12G>T | Intron (SNP) | VAF 35/242 reads (14%) | called by muse, varscan2
- LINC02740 | n.169C>A | RNA (SNP) | VAF 47/347 reads (14%) | called by muse, mutect2, varscan2
- MMAB | c.*1726A>T | 3'UTR (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- MS4A6A | c.282+136G>T | Intron (SNP) | VAF 6/112 reads (5%) | catalogued as rs996768797; called by muse, mutect2
- NCF1C | n.958G>A | RNA (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- NDUFS3 | c.232-86C>G | Intron (SNP) | VAF 30/558 reads (5%) | catalogued as COSV99772471; called by muse, mutect2
- NDUFS3 | c.507+46G>C | Intron (SNP) | VAF 28/456 reads (6%) | called by muse, mutect2
- NR2E1 | c.25+1309C>G | Intron (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- OR5E1P | n.719C>A | RNA (SNP) | VAF 49/337 reads (15%) | called by muse, mutect2, varscan2
- OR7E5P | n.405T>G | RNA (SNP) | VAF 40/436 reads (9%) | called by muse, mutect2
- OVCH1-AS1 | n.255G>A | RNA (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- PHACTR2 | c.421+1405C>G | Intron (SNP) | VAF 21/332 reads (6%) | called by muse, mutect2
- POFUT2 | c.1137-551G>T | Intron (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577413 C>G | 3'Flank (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- PSG8 | chr19:42753374 A>C | 3'Flank (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- PTK2 | c.-32-30063C>G | Intron (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- RAP1GAP2 | c.-27G>T | 5'UTR (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- RIMS2 | c.698+52950G>T | Intron (SNP) | VAF 56/314 reads (18%) | catalogued as rs79393780, COSV99198567; called by mutect2, varscan2
- RPGR | c.2520+728G>A | Intron (SNP) | VAF 8/61 reads (13%) | catalogued as rs1218098015; called by mutect2, varscan2
- RPL37AP1 | chr20:44462104 G>T | 3'Flank (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- RWDD3 | c.86-4335C>T | Intron (SNP) | VAF 18/348 reads (5%) | called by muse, mutect2
- SHISA6 | c.799+115921G>T | Intron (SNP) | VAF 15/217 reads (7%) | called by muse, mutect2
- SLC12A5 | c.122-5575A>G | Intron (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18568C>T | Intron (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*883A>G | 3'UTR (SNP) | VAF 38/559 reads (7%) | catalogued as rs562252318; called by muse, mutect2
- SMYD3 | c.531+843C>G | Intron (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- STIP1 | c.-80G>A | 5'UTR (SNP) | VAF 41/425 reads (10%) | catalogued as rs550349338; called by muse, mutect2
- TBX19 | c.917-12T>A | Intron (SNP) | VAF 59/351 reads (17%) | called by muse, mutect2, varscan2
- TRAT1 | c.152+25C>A | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- TRIM7 | c.989-23C>G | Intron (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- ZFHX2 | c.2934+35G>T | Intron (SNP) | VAF 41/283 reads (14%) | called by muse, mutect2, varscan2
